Somatic mutation profile of tumor specimen C3L-01000-04 (aliquot CPT0123350009) from CPTAC case C3L-01000, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 59.7 years (21,800 days).
Specimen C3L-01000-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4b044818-666e-4bd8-86ee-e7b923120b83.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01000-31 (Blood Derived Normal), aliquot CPT0124800002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2461969c-2ddc-46f0-ac44-09314f6fb69c

The open-access MAF lists 556 somatic variants for this specimen: 385 protein-altering or splice-affecting, 105 silent, 66 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 334, Silent 105, Intron 31, Nonsense Mutation 19, Frame Shift Del 13, Splice Site 11, RNA 10, 5'UTR 9, 3'UTR 7, 5'Flank 7, Splice Region 4, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CRAT | c.962G>A p.R321H | Missense Mutation (SNP) | VAF 69/159 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs138665095; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.488A>G p.Y163C | Missense Mutation (SNP) | VAF 169/512 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148924904, CM942135, COSV52663142, COSV52676381; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.5413G>T p.V1805L | Missense Mutation (SNP) | VAF 41/305 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs555037483; called by muse, mutect2, varscan2
- ADAMTS14 | c.1856C>T p.A619V | Missense Mutation (SNP) | VAF 119/397 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.038); catalogued as COSV64601531; called by muse, mutect2, varscan2
- ADAMTS7 | c.2275G>C p.G759R | Missense Mutation (SNP) | VAF 269/810 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101183241, COSV66306895; called by muse, mutect2, varscan2
- ANAPC1 | c.4774T>G p.F1592V | Missense Mutation (SNP) | VAF 36/748 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV61974894; called by muse, mutect2
- ANXA9 | c.403G>A p.V135M | Missense Mutation (SNP) | VAF 63/241 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs773735585, COSV64485556; called by muse, mutect2, varscan2
- APOBR | c.3196G>A p.G1066R (on ENST00000431282; = p.G1075R on NM_018690.4) | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.789); catalogued as rs759690710, COSV60493675; called by muse, mutect2, varscan2
- ARHGAP9 | c.223C>A p.P75T | Missense Mutation (SNP) | VAF 91/643 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62722014; called by muse, mutect2, varscan2
- ARMC3 | c.1195G>T p.G399C | Missense Mutation (SNP) | VAF 81/258 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs765687705; called by muse, mutect2, varscan2
- ASTN1 | c.613C>G p.P205A | Missense Mutation (SNP) | VAF 40/332 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV56082361; called by muse, mutect2, varscan2
- ASTN2 | c.928C>A p.R310S | Missense Mutation (SNP) | VAF 72/235 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.07); catalogued as COSV100526836; called by muse, mutect2, varscan2
- ATM | c.3154-1G>T p.X1052_splice | Splice Site (SNP) | VAF 108/435 reads (25%) | catalogued as COSV53753080, COSV53757872; called by muse, mutect2, varscan2
- BAMBI | c.778G>A p.V260I | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs774017062, CM163991; called by muse, mutect2
- BLZF1 | c.10A>G p.K4E | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1194041459; called by muse, mutect2, varscan2
- BRD3 | c.1154C>T p.S385L | Missense Mutation (SNP) | VAF 84/289 reads (29%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.995); catalogued as rs757600108, COSV57702117; called by muse, mutect2, varscan2
- BRINP3 | c.1972C>A p.L658M | Missense Mutation (SNP) | VAF 118/483 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.927); catalogued as COSV99054927; called by muse, mutect2, varscan2
- C4orf54 | c.2926C>A p.L976I | Missense Mutation (SNP) | VAF 130/343 reads (38%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.807); catalogued as rs1483970858; called by muse, mutect2, varscan2
- CAD | c.6641G>T p.R2214L | Missense Mutation (SNP) | VAF 120/561 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53032331; called by muse, mutect2, varscan2
- CALD1 | c.335A>G p.Q112R | Missense Mutation (SNP) | VAF 83/310 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as COSV62645034; called by muse, mutect2, varscan2
- CCDC83 | c.255G>C p.E85D | Missense Mutation (SNP) | VAF 86/399 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV99721491; called by muse, mutect2, varscan2
- CDK15 | c.1058+1G>A p.X353_splice (on ENST00000652192 / NM_001366386.2; = p.X302_splice on NM_139158.2) | Splice Site (SNP) | VAF 125/519 reads (24%) | catalogued as rs781412173, COSV53637484; called by muse, mutect2, varscan2
- CEP126 | c.2791G>A p.V931I | Missense Mutation (SNP) | VAF 70/225 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.011); catalogued as rs1475813583; called by muse, mutect2, varscan2
- CHD3 | c.5854C>T p.Q1952* (on ENST00000330494 / NM_001005273.3; = p.Q1918* on NM_005852.4) | Nonsense Mutation (SNP) | VAF 133/431 reads (31%) | catalogued as COSV100177163; called by muse, mutect2, varscan2
- COL21A1 | c.1283G>T p.G428V | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.444); catalogued as COSV55182404; called by muse, mutect2
- COL4A1 | c.903+2T>A p.X301_splice | Splice Site (SNP) | VAF 173/520 reads (33%) | catalogued as COSV101011071; called by muse, mutect2, varscan2
- CSMD3 | c.10877C>A p.T3626K (on ENST00000297405 / NM_001363185.1; = p.T3457K on NM_052900.3) | Missense Mutation (SNP) | VAF 50/339 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99841242; called by muse, mutect2, varscan2
- CST1 | c.94G>C p.G32R | Missense Mutation (SNP) | VAF 76/878 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.75); catalogued as COSV100494376; called by muse, mutect2
- CXCR1 | c.850G>A p.G284S | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs147510072, COSV55283029; called by muse, mutect2, varscan2
- CYLC1 | c.1463C>G p.S488C | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV61415873; called by muse, mutect2, varscan2
- DACH1 | c.1975G>C p.E659Q (on ENST00000619232 / NM_001366712.1; = p.E405Q on NM_004392.6) | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV57509832; called by muse, mutect2, varscan2
- DCHS1 | c.3391G>T p.D1131Y | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV104408709; called by muse, mutect2, varscan2
- DCLK3 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as COSV69365184; called by muse, mutect2, varscan2
- DDAH2 | c.570C>G p.D190E | Missense Mutation (SNP) | VAF 16/430 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV101007420; called by muse, mutect2
- DHX34 | c.2560G>T p.A854S | Missense Mutation (SNP) | VAF 232/902 reads (26%) | SIFT tolerated (0.78); PolyPhen benign (0.094); catalogued as rs200310017; called by muse, mutect2, varscan2
- DNAH10 | c.11274G>A p.M3758I (on ENST00000409039; = p.M3697I on NM_207437.3) | Missense Mutation (SNP) | VAF 49/159 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1309714353; called by muse, mutect2, varscan2
- EFCAB6 | c.2893C>G p.R965G | Missense Mutation (SNP) | VAF 20/161 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs746756725, COSV99034696; called by muse, mutect2, varscan2
- ELAC1 | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 11/141 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV53997202; called by muse, mutect2
- F13B | c.1831T>C p.Y611H | Missense Mutation (SNP) | VAF 50/288 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs770292850; called by muse, mutect2, varscan2
- FAM135B | c.2543C>A p.P848H | Missense Mutation (SNP) | VAF 92/472 reads (19%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.005); catalogued as COSV52702171; called by muse, mutect2, varscan2
- FAT3 | c.12028G>A p.G4010S | Missense Mutation (SNP) | VAF 55/508 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV53112272; called by muse, mutect2, varscan2
- FBL | c.140G>T p.G47V | Missense Mutation (SNP) | VAF 79/253 reads (31%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.066); catalogued as COSV55681995; called by muse, mutect2, varscan2
- FGD6 | c.3958A>G p.I1320V | Missense Mutation (SNP) | VAF 23/178 reads (13%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.991); catalogued as COSV59693101; called by muse, mutect2, varscan2
- FLG | c.6363G>C p.Q2121H | Missense Mutation (SNP) | VAF 89/740 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.053); catalogued as rs761105257; called by muse, mutect2, varscan2
- FUT6 | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 300/908 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs141945646; called by muse, mutect2, varscan2
- GALNT10 | c.1389C>A p.I463= | Splice Region (SNP) | VAF 27/378 reads (7%) | catalogued as COSV51729062; called by muse, mutect2
- GGT5 | c.1318G>A p.G440S | Missense Mutation (SNP) | VAF 26/486 reads (5%) | SIFT tolerated (0.82); PolyPhen benign (0.015); catalogued as rs748665403; called by muse, mutect2
- GLI3 | c.3018C>G p.S1006R | Missense Mutation (SNP) | VAF 54/408 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM127565, COSV67890742; called by muse, mutect2, varscan2
- GPR84 | c.1024G>T p.D342Y | Missense Mutation (SNP) | VAF 74/237 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749758853, COSV99910097; called by muse, mutect2, varscan2
- GRIK5 | c.1315G>T p.G439W | Missense Mutation (SNP) | VAF 111/509 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99489937; called by muse, mutect2, varscan2
- HCFC2 | c.1132G>T p.D378Y | Missense Mutation (SNP) | VAF 34/254 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as rs367627562; called by muse, mutect2, varscan2
- HEATR9 | c.-2_1del | Translation Start Site (DEL) | VAF 24/142 reads (17%) | catalogued as rs1295354237; called by pindel, varscan2
- HECW2 | c.812G>T p.R271L | Missense Mutation (SNP) | VAF 64/319 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV53673584; called by muse, mutect2, varscan2
- HELB | c.3062C>T p.S1021L | Missense Mutation (SNP) | VAF 52/343 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs868455893, COSV99921963; called by muse, mutect2, varscan2
- HELZ2 | c.1823G>A p.R608Q (on ENST00000467148 / NM_001037335.2; = p.R39Q on NM_033405.3) | Missense Mutation (SNP) | VAF 218/904 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.954); catalogued as COSV64409637; called by muse, mutect2, varscan2
- HGF | c.498C>G p.S166R | Missense Mutation (SNP) | VAF 85/294 reads (29%) | SIFT tolerated (1); PolyPhen probably damaging (0.944); catalogued as COSV55955516, COSV55956649; called by muse, mutect2, varscan2
- HSD17B4 | c.1340A>T p.K447I (on ENST00000414835 / NM_001199291.3; = p.K422I on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/191 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as rs751930586; called by muse, mutect2, varscan2
- IGKV3D-20 | c.43C>T p.L15F | Missense Mutation (SNP) | VAF 71/396 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.048); catalogued as rs772525452; called by muse, mutect2, varscan2
- ITGA6 | c.1004T>G p.M335R (on ENST00000442250; = p.M296R on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 232/726 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0.053); catalogued as COSV51289227; called by muse, mutect2, varscan2
- KANSL1L | c.400A>C p.K134Q | Missense Mutation (SNP) | VAF 65/377 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); catalogued as COSV55992733; called by muse, mutect2, varscan2
- KEAP1 | c.1381A>G p.I461V | Missense Mutation (SNP) | VAF 53/275 reads (19%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.484); catalogued as COSV50260791, COSV50349793; called by muse, mutect2, varscan2
- KLHL1 | c.586G>T p.E196* | Nonsense Mutation (SNP) | VAF 22/123 reads (18%) | catalogued as COSV64772523, COSV64777755; called by muse, mutect2, varscan2
- KMT2C | c.7087G>C p.G2363R | Missense Mutation (SNP) | VAF 45/247 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV100066928; called by muse, mutect2, varscan2
- KRT1 | c.779A>G p.Q260R | Missense Mutation (SNP) | VAF 37/331 reads (11%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.985); catalogued as rs767646106; called by muse, mutect2, varscan2
- KRT74 | c.849C>G p.I283M | Missense Mutation (SNP) | VAF 72/650 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.318); catalogued as COSV99977539; called by muse, mutect2, varscan2
- LILRA4 | c.670C>T p.P224S | Missense Mutation (SNP) | VAF 35/240 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1232888368, COSV99393402; called by muse, mutect2, varscan2
- LILRB2 | c.935C>A p.P312H | Missense Mutation (SNP) | VAF 74/359 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV58744217; called by muse, mutect2, varscan2
- LRP1B | c.2545G>C p.E849Q | Missense Mutation (SNP) | VAF 72/273 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.168); catalogued as COSV63342053; called by muse, mutect2, varscan2
- MS4A18 | c.808G>T p.V270F (on ENST00000398983; = p.V272F on NM_001354471.1) | Missense Mutation (SNP) | VAF 101/556 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as rs1271467086; called by muse, mutect2, varscan2
- MUC5B | c.5980C>T p.R1994C | Missense Mutation (SNP) | VAF 335/1354 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.14); catalogued as rs1410463916; called by muse, mutect2, varscan2
- MYH9 | c.3805A>G p.T1269A | Missense Mutation (SNP) | VAF 124/850 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1244168341; called by muse, mutect2, varscan2
- MYT1L | c.898G>T p.V300F | Missense Mutation (SNP) | VAF 96/417 reads (23%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.307); catalogued as COSV67707093; called by muse, mutect2, varscan2
- NEURL4 | c.535G>C p.G179R | Missense Mutation (SNP) | VAF 94/256 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1164746049, COSV100223718; called by muse, mutect2, varscan2
- NF1 | c.2323G>T p.E775* | Nonsense Mutation (SNP) | VAF 120/467 reads (26%) | catalogued as COSV62203851; called by muse, mutect2, varscan2
- NID2 | c.1324G>A p.E442K | Missense Mutation (SNP) | VAF 144/560 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.019); catalogued as COSV53493996, COSV53501423; called by muse, mutect2, varscan2
- NPAP1 | c.109C>T p.R37W | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as rs1206282536, COSV61504665; called by muse, mutect2, varscan2
- NXPE3 | c.715A>G p.T239A | Missense Mutation (SNP) | VAF 190/465 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99066584; called by muse, mutect2, varscan2
- OR2T27 | c.791C>A p.S264Y | Missense Mutation (SNP) | VAF 36/169 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV61282815; called by muse, mutect2, varscan2
- OR4L1 | c.419T>C p.L140P | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.722); catalogued as rs749984367, COSV59850623; called by muse, mutect2
- OR5D18 | c.650C>A p.T217K | Missense Mutation (SNP) | VAF 97/473 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as rs757403859, COSV100450663, COSV61738993; called by muse, mutect2, varscan2
- OR5I1 | c.584C>A p.T195K | Missense Mutation (SNP) | VAF 50/201 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.023); catalogued as rs764291333; called by muse, mutect2, varscan2
- OR5K1 | c.650C>G p.S217C | Missense Mutation (SNP) | VAF 28/312 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60303819; called by muse, mutect2
- OR6K2 | c.547G>C p.V183L | Missense Mutation (SNP) | VAF 30/242 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.052); catalogued as COSV62743438; called by muse, mutect2, varscan2
- OR6T1 | c.951G>T p.R317S | Missense Mutation (SNP) | VAF 58/222 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV100189845; called by muse, mutect2, varscan2
- OR8J3 | c.235C>G p.P79A | Missense Mutation (SNP) | VAF 46/281 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.226); catalogued as COSV100040895, COSV56880985; called by muse, mutect2, varscan2
- OR9G1 | c.104C>G p.S35C | Missense Mutation (SNP) | VAF 102/996 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV56452123; called by muse, mutect2, varscan2
- PBXIP1 | c.384G>T p.Q128H | Missense Mutation (SNP) | VAF 71/324 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV100870118; called by muse, mutect2, varscan2
- PCDHB13 | c.2258T>A p.V753E | Missense Mutation (SNP) | VAF 106/341 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as COSV99507454; called by muse, mutect2, varscan2
- PIANP | c.288del p.P97Rfs*123 | Frame Shift Del (DEL) | VAF 178/729 reads (24%) | catalogued as rs757955708; called by mutect2, pindel, varscan2
- PIGS | c.419G>A p.G140D | Missense Mutation (SNP) | VAF 26/363 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.951); catalogued as rs1039063076; called by muse, mutect2
- PPP1R3A | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 67/245 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs766674245; called by muse, mutect2, varscan2
- PRICKLE1 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 67/710 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.072); catalogued as rs1457774536, COSV61543203; called by muse, mutect2
- PRSS36 | c.1166C>G p.P389R | Missense Mutation (SNP) | VAF 58/146 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.631); catalogued as COSV51638582; called by muse, mutect2, varscan2
- QRSL1 | c.760del p.D254Tfs*21 | Frame Shift Del (DEL) | VAF 27/164 reads (16%) | catalogued as COSV100945262; called by mutect2, pindel, varscan2
- QTRT1 | c.799C>G p.L267V | Missense Mutation (SNP) | VAF 119/374 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as rs1346888116; called by muse, mutect2, varscan2
- RYR3 | c.3223C>G p.R1075G | Missense Mutation (SNP) | VAF 70/539 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66799887; called by muse, mutect2, varscan2
- SAMM50 | c.540del p.G182Efs*9 | Frame Shift Del (DEL) | VAF 32/170 reads (19%) | catalogued as COSV63109260; called by mutect2, pindel
- SAPCD2 | c.667G>A p.G223S | Missense Mutation (SNP) | VAF 156/447 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs150716976; called by muse, mutect2, varscan2
- SCN7A | c.574G>T p.V192F | Missense Mutation (SNP) | VAF 41/180 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV69272802; called by muse, mutect2, varscan2
- SEC16A | c.254G>A p.G85E | Missense Mutation (SNP) | VAF 100/291 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.535); catalogued as rs1164892381; called by muse, mutect2, varscan2
- SLC2A12 | c.579C>A p.F193L | Missense Mutation (SNP) | VAF 79/327 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV51600740; called by muse, mutect2, varscan2
- SLC35F5 | c.460A>G p.T154A | Missense Mutation (SNP) | VAF 60/270 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs760677524; called by muse, mutect2, varscan2
- SLC6A17 | c.925T>A p.L309M | Missense Mutation (SNP) | VAF 42/275 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58992873; called by muse, mutect2, varscan2
- SLC6A4 | c.272C>T p.S91L | Missense Mutation (SNP) | VAF 52/294 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99911377; called by muse, mutect2, varscan2
- SLITRK5 | c.2648G>T p.S883I | Missense Mutation (SNP) | VAF 53/161 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV100281075; called by muse, mutect2, varscan2
- SMCO2 | c.427G>T p.E143* | Nonsense Mutation (SNP) | VAF 70/320 reads (22%) | catalogued as COSV100103498; called by muse, mutect2, varscan2
- SPON1 | c.2170C>T p.P724S | Missense Mutation (SNP) | VAF 162/684 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV59965927; called by muse, mutect2, varscan2
- SULT1A2 | c.808G>A p.V270M | Missense Mutation (SNP) | VAF 156/664 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs200765354, COSV57683434; called by muse, mutect2, varscan2
- TERF2IP | c.866G>C p.G289A | Missense Mutation (SNP) | VAF 57/166 reads (34%) | SIFT tolerated, low confidence (0.75); catalogued as rs1334376106; called by muse, mutect2, varscan2
- TFDP3 | c.236C>A p.P79H | Missense Mutation (SNP) | VAF 91/184 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV59536481; called by muse, mutect2, varscan2
- TNFRSF18 | c.686C>T p.S229L | Missense Mutation (SNP) | VAF 78/477 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763921252, COSV60775094; called by muse, mutect2, varscan2
- TOX2 | c.1024G>C p.D342H (on ENST00000358131 / NM_001098798.2; = p.D318H on NM_032883.3) | Missense Mutation (SNP) | VAF 162/490 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs866580051; called by muse, mutect2, varscan2
- TRIM11 | c.701G>T p.G234V | Missense Mutation (SNP) | VAF 41/205 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs770229664; called by muse, mutect2
- TSHR | c.434C>A p.T145N | Missense Mutation (SNP) | VAF 115/447 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as CM116324; called by mutect2, varscan2
- TTN | c.28279C>A p.R9427S (on ENST00000591111; = p.R8500S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 80/278 reads (29%) | PolyPhen probably damaging (0.998); catalogued as COSV60057699; called by muse, mutect2, varscan2
- TWIST1 | c.338C>A p.A113D | Missense Mutation (SNP) | VAF 73/229 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99642943; called by muse, mutect2, varscan2
- USP43 | c.3221G>C p.R1074P | Missense Mutation (SNP) | VAF 66/214 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as COSV53301479; called by muse, mutect2, varscan2
- VSTM2B | c.58G>T p.A20S | Missense Mutation (SNP) | VAF 158/709 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs772441189; called by muse, mutect2, varscan2
- WASHC2C | c.3034G>A p.G1012S (on ENST00000336378; = p.G991S on NM_015262.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/521 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.88); catalogued as rs782201306; called by muse, mutect2
- WDR92 | c.662A>C p.D221A | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as COSV99718305; called by muse, mutect2, varscan2
- WNT10A | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 149/595 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.475); catalogued as rs760336599; called by muse, mutect2, varscan2
- WRAP73 | c.1143G>T p.W381C | Missense Mutation (SNP) | VAF 152/676 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54562928; called by muse, mutect2, varscan2
- ZFYVE28 | c.2066G>C p.G689A | Missense Mutation (SNP) | VAF 28/172 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs769909463; called by muse, mutect2, varscan2
- ZFYVE9 | c.4223G>A p.S1408N | Missense Mutation (SNP) | VAF 23/195 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1228060015; called by muse, mutect2, varscan2
- ZIM3 | c.1148A>C p.K383T | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as rs1168907747; called by muse, mutect2
- ZNF469 | c.2096G>T p.R699L | Missense Mutation (SNP) | VAF 122/306 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.328); catalogued as COSV71259426; called by muse, varscan2
- ZNF516 | c.387C>A p.N129K | Missense Mutation (SNP) | VAF 81/507 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs779202060; called by muse, mutect2, varscan2
- ZNF540 | c.100G>C p.V34L | Missense Mutation (SNP) | VAF 16/338 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV100143785; called by muse, mutect2
- ZNF616 | c.2240G>T p.C747F | Missense Mutation (SNP) | VAF 51/203 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1309161702; called by muse, mutect2, varscan2
- ZNF679 | c.1037A>G p.H346R | Missense Mutation (SNP) | VAF 46/356 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1218746740; called by muse, mutect2, varscan2
- ZNF729 | c.1577G>A p.S526N | Missense Mutation (SNP) | VAF 109/457 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs879098229; called by muse, mutect2, varscan2
- ACACB | c.3232C>A p.Q1078K | Missense Mutation (SNP) | VAF 32/198 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- ACSL1 | c.202G>T p.G68C | Missense Mutation (SNP) | VAF 75/214 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- ADAMTS8 | c.2347C>A p.P783T | Missense Mutation (SNP) | VAF 89/335 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- ADCY5 | c.3475A>T p.M1159L | Missense Mutation (SNP) | VAF 30/985 reads (3%) | SIFT tolerated (0.15); PolyPhen benign (0.326); called by muse, mutect2
- ADGRB1 | c.1151C>A p.S384Y | Missense Mutation (SNP) | VAF 185/497 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- ADGRL3 | c.3635G>T p.S1212I (on ENST00000506720 / NM_001322402.2; = p.S1144I on NM_015236.6) | Missense Mutation (SNP) | VAF 69/245 reads (28%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- AFF3 | c.220G>T p.G74C | Missense Mutation (SNP) | VAF 59/226 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AGXT | c.391G>T p.G131* | Nonsense Mutation (SNP) | VAF 66/510 reads (13%) | called by muse, mutect2, varscan2
- AGXT | c.392G>T p.G131V | Missense Mutation (SNP) | VAF 63/502 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AHCTF1 | c.4541A>T p.N1514I (on ENST00000366508; = p.N1488I on NM_015446.5) | Missense Mutation (SNP) | VAF 42/251 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- AL645922.1 | c.963C>G p.D321E | Missense Mutation (SNP) | VAF 101/735 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- AMER3 | c.991G>T p.G331C | Missense Mutation (SNP) | VAF 117/470 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- ANKRD30A | c.377T>G p.I126R (on ENST00000611781; = p.I70R on NM_052997.2) | Missense Mutation (SNP) | VAF 99/466 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ANO5 | c.1256A>G p.E419G | Missense Mutation (SNP) | VAF 94/401 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- APOBR | c.3197G>T p.G1066V (on ENST00000431282; = p.G1075V on NM_018690.4) | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ARID2 | c.3769C>G p.H1257D | Missense Mutation (SNP) | VAF 55/422 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ASPDH | c.133G>A p.G45R | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ATP2B2 | c.499G>T p.V167F | Missense Mutation (SNP) | VAF 199/617 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BCL11B | c.2202G>T p.Q734H (on ENST00000357195 / NM_001282237.2; = p.Q663H on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 269/702 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- BCO2 | c.866-2A>C p.X289_splice | Splice Site (SNP) | VAF 44/172 reads (26%) | called by muse, varscan2
- BDH1 | c.728del p.A243Vfs*64 | Frame Shift Del (DEL) | VAF 148/824 reads (18%) | called by mutect2, pindel, varscan2
- BDP1 | c.5836A>G p.N1946D | Missense Mutation (SNP) | VAF 55/196 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- BGN | c.1097A>T p.Y366F | Missense Mutation (SNP) | VAF 135/276 reads (49%) | SIFT tolerated (0.43); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- BICD2 | c.318G>T p.E106D | Missense Mutation (SNP) | VAF 95/341 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- BICRAL | c.483G>C p.Q161H | Missense Mutation (SNP) | VAF 48/380 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- C16orf96 | c.561C>A p.D187E | Missense Mutation (SNP) | VAF 27/248 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- C2 | c.752G>T p.G251V | Missense Mutation (SNP) | VAF 103/675 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- CACNA1H | c.754T>C p.W252R | Missense Mutation (SNP) | VAF 50/322 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CACNA1H | c.4999A>C p.K1667Q | Missense Mutation (SNP) | VAF 87/663 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CACNA1S | c.5448T>A p.D1816E | Missense Mutation (SNP) | VAF 119/730 reads (16%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CACNA2D4 | c.430_431insA p.L144Hfs*16 | Frame Shift Ins (INS) | VAF 85/398 reads (21%) | called by mutect2, pindel, varscan2
- CAND1 | c.3296G>T p.R1099I | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- CAPN13 | c.1665dup p.G556Wfs*55 | Frame Shift Ins (INS) | VAF 56/400 reads (14%) | called by mutect2, pindel, varscan2
- CARD18 | c.145A>C p.T49P | Missense Mutation (SNP) | VAF 112/500 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.518); called by muse, mutect2, varscan2
- CARM1 | c.813C>G p.S271R | Missense Mutation (SNP) | VAF 69/402 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- CATSPER2 | c.1197G>C p.R399S (on ENST00000321596 / NM_001282309.3; = p.R401S on NM_172095.4) | Missense Mutation (SNP) | VAF 55/247 reads (22%) | SIFT tolerated (0.76); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCDC103 | c.433G>C p.G145R | Missense Mutation (SNP) | VAF 77/619 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCSER1 | c.478G>T p.D160Y | Missense Mutation (SNP) | VAF 85/264 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCSER1 | c.1677A>G p.I559M | Missense Mutation (SNP) | VAF 50/188 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- CD163 | c.1864C>T p.Q622* | Nonsense Mutation (SNP) | VAF 77/261 reads (30%) | called by muse, mutect2, varscan2
- CD5L | c.145T>C p.C49R | Missense Mutation (SNP) | VAF 125/503 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDCA2 | c.2558C>G p.S853C | Missense Mutation (SNP) | VAF 92/381 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CDH15 | c.925T>C p.F309L | Missense Mutation (SNP) | VAF 201/484 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); called by muse, varscan2
- CDH23 | c.5741T>A p.L1914Q | Missense Mutation (SNP) | VAF 36/262 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CGB5 | c.278C>T p.P93L | Missense Mutation (SNP) | VAF 96/1101 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- CHADL | c.1449C>A p.N483K | Missense Mutation (SNP) | VAF 42/225 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHML | c.1531A>G p.T511A | Missense Mutation (SNP) | VAF 78/275 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHRNA6 | c.881C>G p.P294R | Missense Mutation (SNP) | VAF 226/480 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CKAP5 | c.1796T>G p.V599G | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CMBL | c.87C>A p.H29Q | Missense Mutation (SNP) | VAF 57/736 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); called by muse, mutect2
- COG1 | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 50/395 reads (13%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- COG2 | c.1667C>G p.S556C | Missense Mutation (SNP) | VAF 37/231 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- COL19A1 | c.205T>G p.F69V | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.057); called by muse, mutect2
- COL24A1 | c.3373G>C p.G1125R | Missense Mutation (SNP) | VAF 22/214 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL4A4 | c.355G>C p.G119R | Missense Mutation (SNP) | VAF 43/265 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL6A6 | c.5648C>A p.T1883K | Missense Mutation (SNP) | VAF 117/547 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- COL7A1 | c.8314G>T p.G2772W | Missense Mutation (SNP) | VAF 319/920 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CRYBG3 | c.446A>T p.Q149L | Missense Mutation (SNP) | VAF 79/425 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- CST1 | c.372A>T p.E124D | Missense Mutation (SNP) | VAF 34/704 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.069); called by muse, mutect2
- CTH | c.1135G>A p.G379S | Missense Mutation (SNP) | VAF 63/420 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CUL4A | c.1610C>A p.T537K (on ENST00000375440 / NM_001008895.4; = p.T437K on NM_003589.3) | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.02); called by muse, mutect2
- CUX2 | c.3439C>T p.P1147S | Missense Mutation (SNP) | VAF 62/244 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CYRIB | c.722G>A p.R241K | Missense Mutation (SNP) | VAF 8/227 reads (4%) | SIFT tolerated (0.37); PolyPhen benign (0.013); called by muse, mutect2
- DECR1 | c.775G>T p.E259* | Nonsense Mutation (SNP) | VAF 47/307 reads (15%) | called by muse, varscan2
- DFFA | c.83G>T p.S28I | Missense Mutation (SNP) | VAF 93/356 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- DISP3 | c.4043C>T p.S1348F | Missense Mutation (SNP) | VAF 115/503 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNA2 | c.2451G>C p.K817N | Missense Mutation (SNP) | VAF 37/343 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- DNAH1 | c.2587G>T p.E863* | Nonsense Mutation (SNP) | VAF 121/365 reads (33%) | called by mutect2, varscan2
- DNAH11 | c.2483A>T p.E828V | Missense Mutation (SNP) | VAF 44/350 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, varscan2
- DNAH6 | c.9307C>A p.L3103I | Missense Mutation (SNP) | VAF 36/174 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- DOCK1 | c.1377del p.K460Nfs*3 | Frame Shift Del (DEL) | VAF 60/218 reads (28%) | called by mutect2, pindel, varscan2
- DSC3 | c.1037C>A p.T346K | Missense Mutation (SNP) | VAF 56/502 reads (11%) | SIFT tolerated (0.61); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DSG4 | c.620C>T p.P207L | Missense Mutation (SNP) | VAF 110/478 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- DST | c.9512C>T p.T3171I | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- DYSF | c.750G>C p.K250N | Missense Mutation (SNP) | VAF 111/466 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- EFCAB12 | c.1324T>C p.Y442H | Missense Mutation (SNP) | VAF 46/278 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ENPP2 | c.1775C>T p.T592I (on ENST00000075322 / NM_001040092.3; = p.T644I on NM_006209.5) | Missense Mutation (SNP) | VAF 228/479 reads (48%) | SIFT tolerated (0.43); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- ENTPD5 | c.299G>T p.G100V | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- F13B | c.1792T>C p.W598R | Missense Mutation (SNP) | VAF 43/250 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- FAAH2 | c.865C>A p.P289T | Missense Mutation (SNP) | VAF 142/304 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.574); called by muse, mutect2, varscan2
- FANCI | c.880A>G p.K294E | Missense Mutation (SNP) | VAF 112/381 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FCRL4 | c.882G>T p.Q294H | Missense Mutation (SNP) | VAF 8/178 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.087); called by muse, mutect2
- FUBP1 | c.1672G>T p.G558C | Missense Mutation (SNP) | VAF 33/244 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.574); called by muse, mutect2, varscan2
- FURIN | c.1481_1485del p.S494* | Frame Shift Del (DEL) | VAF 72/267 reads (27%) | called by mutect2, pindel, varscan2
- GBF1 | c.265G>A p.V89I | Missense Mutation (SNP) | VAF 73/232 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- GCAT | c.815-2A>T p.X272_splice | Splice Site (SNP) | VAF 68/240 reads (28%) | called by muse, mutect2, varscan2
- GIMAP4 | c.76C>A p.P26T | Missense Mutation (SNP) | VAF 44/126 reads (35%) | SIFT tolerated (0.56); PolyPhen benign (0.113); called by muse, mutect2
- GMEB2 | c.788G>T p.G263V | Missense Mutation (SNP) | VAF 91/474 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- GPATCH1 | c.52G>T p.G18W | Missense Mutation (SNP) | VAF 60/596 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- GPR148 | c.53T>A p.L18Q | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- GREB1 | c.1954+1G>C p.X652_splice | Splice Site (SNP) | VAF 9/113 reads (8%) | called by muse, mutect2
- GTF3C1 | c.859G>T p.E287* | Nonsense Mutation (SNP) | VAF 64/596 reads (11%) | called by muse, mutect2, varscan2
- HAO1 | c.799G>C p.G267R | Missense Mutation (SNP) | VAF 64/258 reads (25%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- HCN1 | c.838C>T p.Q280* | Nonsense Mutation (SNP) | VAF 43/189 reads (23%) | called by muse, mutect2, varscan2
- HECTD4 | c.1137C>G p.F379L | Missense Mutation (SNP) | VAF 85/268 reads (32%) | SIFT tolerated (0.96); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- HECW2 | c.4330A>G p.R1444G | Missense Mutation (SNP) | VAF 37/342 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HMCN1 | c.5648del p.L1883Hfs*46 | Frame Shift Del (DEL) | VAF 73/559 reads (13%) | called by mutect2, pindel, varscan2
- IFNA14 | c.339C>A p.F113L | Missense Mutation (SNP) | VAF 205/645 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- IL23R | c.1240-2A>T p.X414_splice | Splice Site (SNP) | VAF 9/50 reads (18%) | called by muse, mutect2, varscan2
- INSM1 | c.20T>C p.V7A | Missense Mutation (SNP) | VAF 26/248 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2
- IPO11 | c.1354G>A p.A452T | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- IQSEC1 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 64/198 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- IQSEC2 | c.1169T>A p.M390K (on ENST00000642864 / NM_001111125.3; = p.M185K on NM_015075.2) | Missense Mutation (SNP) | VAF 126/288 reads (44%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- ISM2 | c.353C>A p.T118K | Missense Mutation (SNP) | VAF 116/754 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ISX | c.98T>A p.I33N | Missense Mutation (SNP) | VAF 247/724 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ITPRIPL2 | c.1493C>T p.S498F | Missense Mutation (SNP) | VAF 96/345 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- KCNH7 | c.3420G>C p.L1140F | Missense Mutation (SNP) | VAF 64/286 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- KCNIP1 | c.311del p.Y104Sfs*14 (on ENST00000411494 / NM_001034837.3; = p.Y93Sfs*14 on NM_014592.4) | Frame Shift Del (DEL) | VAF 95/381 reads (25%) | called by mutect2, pindel, varscan2
- KDM4A | c.223G>T p.V75L | Missense Mutation (SNP) | VAF 29/271 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- KDM5B | c.2833G>T p.G945W | Missense Mutation (SNP) | VAF 27/180 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KHSRP | c.2117del p.G706Dfs*17 | Frame Shift Del (DEL) | VAF 49/175 reads (28%) | called by mutect2, pindel, varscan2
- KIAA1755 | c.640C>A p.P214T | Missense Mutation (SNP) | VAF 158/458 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- KIF14 | c.2476A>G p.T826A | Missense Mutation (SNP) | VAF 36/316 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- KIF2C | c.332C>T p.S111F | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- KIF6 | c.254T>C p.V85A | Missense Mutation (SNP) | VAF 65/247 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- KIF9 | c.753del p.R251Sfs*12 | Frame Shift Del (DEL) | VAF 65/205 reads (32%) | called by mutect2, pindel*, varscan2
- KIR2DS4 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 107/605 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- KLHL20 | c.1738A>T p.T580S | Missense Mutation (SNP) | VAF 22/187 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KRT15 | c.1247+4G>T | Splice Region (SNP) | VAF 24/232 reads (10%) | called by muse, mutect2
- LBX1 | c.470A>G p.Q157R | Missense Mutation (SNP) | VAF 56/181 reads (31%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- LDB2 | c.1052C>G p.P351R | Missense Mutation (SNP) | VAF 79/487 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- LILRB3 | c.74C>A p.P25H | Missense Mutation (SNP) | VAF 80/428 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.014); called by mutect2, varscan2
- LRRIQ3 | c.1191C>A p.D397E | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT tolerated (0.78); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MAP3K20 | c.2117C>G p.S706* | Nonsense Mutation (SNP) | VAF 42/178 reads (24%) | called by muse, mutect2, varscan2
- MAP3K9 | c.2731A>C p.S911R (on ENST00000554752 / NM_001284230.1; = p.S925R on NM_033141.4) | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2
- MAST3 | c.259G>T p.A87S | Missense Mutation (SNP) | VAF 77/583 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MCF2L2 | c.90G>C p.Q30H | Missense Mutation (SNP) | VAF 47/301 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MCM3 | c.2264A>T p.K755M (on ENST00000229854 / NM_001366374.2; = p.K745M on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 102/352 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- MDGA2 | c.494G>C p.R165T | Missense Mutation (SNP) | VAF 44/255 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- MFSD11 | c.1144G>A p.E382K | Missense Mutation (SNP) | VAF 119/441 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MGAT4A | c.1450G>T p.D484Y | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- MICALL2 | c.143+1G>C p.X48_splice | Splice Site (SNP) | VAF 39/222 reads (18%) | called by muse, mutect2, varscan2
- MISP | c.285C>G p.Y95* | Nonsense Mutation (SNP) | VAF 253/832 reads (30%) | called by muse, mutect2, varscan2
- MMP26 | c.280C>G p.P94A | Missense Mutation (SNP) | VAF 111/437 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- MPRIP | c.2726A>T p.K909M | Missense Mutation (SNP) | VAF 33/296 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- MRGPRD | c.785G>T p.R262L | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- MTFR1L | c.695C>G p.S232C | Missense Mutation (SNP) | VAF 55/321 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- MYBPC2 | c.1740G>T p.K580N | Missense Mutation (SNP) | VAF 51/237 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- MYBPC2 | c.1741G>T p.G581* | Nonsense Mutation (SNP) | VAF 48/235 reads (20%) | called by muse, mutect2, varscan2
- MYO16 | c.5488C>A p.P1830T | Missense Mutation (SNP) | VAF 133/415 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MYO5A | c.3111A>T p.E1037D | Missense Mutation (SNP) | VAF 213/694 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- MYOM2 | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 40/484 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); called by muse, mutect2
- NBAS | c.3416G>T p.G1139V | Missense Mutation (SNP) | VAF 85/348 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NCAPG2 | c.2034G>T p.M678I | Missense Mutation (SNP) | VAF 37/145 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- NDUFA4 | c.52C>T p.L18F | Missense Mutation (SNP) | VAF 66/246 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- NELL1 | c.1458C>A p.N486K | Missense Mutation (SNP) | VAF 114/514 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- NEU3 | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 102/414 reads (25%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- NKX2-5 | c.643G>C p.A215P | Missense Mutation (SNP) | VAF 207/666 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.401); called by mutect2, varscan2
- NLRP3 | c.1214C>G p.T405S | Missense Mutation (SNP) | VAF 48/356 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- NMRK2 | c.487A>T p.N163Y | Missense Mutation (SNP) | VAF 60/177 reads (34%) | SIFT tolerated (0.98); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- NPY1R | c.482T>G p.V161G | Missense Mutation (SNP) | VAF 88/234 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.124); called by muse, mutect2
- NRDC | c.893G>T p.G298V | Missense Mutation (SNP) | VAF 64/427 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NRG1 | c.652G>T p.G218* | Nonsense Mutation (SNP) | VAF 63/244 reads (26%) | called by muse, mutect2, varscan2
- NXF5 | n.1096G>C | Splice Region (SNP) | VAF 274/571 reads (48%) | called by muse, mutect2, varscan2
- NXPE1 | c.572C>A p.A191D (on ENST00000424269; = p.A49D on NM_152315.5) | Missense Mutation (SNP) | VAF 105/465 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR10G7 | c.218C>T p.T73I | Missense Mutation (SNP) | VAF 60/461 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- OR13C5 | c.49C>A p.L17I | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.125); called by muse, mutect2
- OR2C3 | c.854C>A p.A285E | Missense Mutation (SNP) | VAF 68/598 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.042); called by muse, varscan2
- OR2C3 | c.842T>A p.V281E | Missense Mutation (SNP) | VAF 62/625 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); called by muse, varscan2
- OR2C3 | c.329C>A p.A110E | Missense Mutation (SNP) | VAF 157/617 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- OR4C16 | c.335T>C p.I112T | Missense Mutation (SNP) | VAF 54/209 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- OR51E1 | c.764T>C p.V255A | Missense Mutation (SNP) | VAF 67/308 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- OR5D18 | c.177del p.M60Cfs*25 | Frame Shift Del (DEL) | VAF 20/116 reads (17%) | called by mutect2, pindel, varscan2
- OTOP1 | c.1714G>C p.G572R | Missense Mutation (SNP) | VAF 21/199 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- PAPOLB | c.559G>A p.D187N | Missense Mutation (SNP) | VAF 31/193 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.427); called by muse, mutect2, varscan2
- PAPPA2 | c.4120G>C p.E1374Q | Missense Mutation (SNP) | VAF 71/578 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- PAX3 | c.664A>G p.S222G | Missense Mutation (SNP) | VAF 44/671 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.752); called by muse, mutect2
- PAX6 | c.1033-7C>A | Splice Region (SNP) | VAF 114/464 reads (25%) | called by muse, mutect2, varscan2
- PBDC1 | c.220G>T p.E74* | Nonsense Mutation (SNP) | VAF 88/187 reads (47%) | called by muse, mutect2, varscan2
- PCDHB9 | c.2195T>G p.F732C | Missense Mutation (SNP) | VAF 14/474 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- PCDHGA5 | c.1721G>A p.G574D | Missense Mutation (SNP) | VAF 197/598 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- PCDHGB3 | c.1402G>A p.G468R | Missense Mutation (SNP) | VAF 128/392 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PDCD10 | c.25A>C p.K9Q | Missense Mutation (SNP) | VAF 15/402 reads (4%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.736); called by muse, mutect2
- PDGFRA | c.119A>T p.Q40L | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PHIP | c.5270A>T p.E1757V | Missense Mutation (SNP) | VAF 62/201 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PHIP | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 121/430 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PIAS4 | c.725C>T p.P242L | Missense Mutation (SNP) | VAF 113/283 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PIEZO2 | c.5361G>T p.R1787S | Missense Mutation (SNP) | VAF 133/673 reads (20%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIEZO2 | c.5360G>T p.R1787M | Missense Mutation (SNP) | VAF 134/673 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIGH | c.488G>T p.R163L | Missense Mutation (SNP) | VAF 41/168 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PLCG2 | c.232A>C p.N78H | Missense Mutation (SNP) | VAF 77/221 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- PLEKHA6 | c.644G>T p.G215V | Missense Mutation (SNP) | VAF 82/534 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PLEKHN1 | c.332A>G p.D111G | Missense Mutation (SNP) | VAF 118/543 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- PLXNA2 | c.2826G>T p.M942I | Missense Mutation (SNP) | VAF 35/271 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- POM121L12 | c.409G>T p.V137L | Missense Mutation (SNP) | VAF 120/585 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- POU5F1B | c.497A>C p.D166A | Missense Mutation (SNP) | VAF 72/888 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); called by muse, mutect2
- PPM1B | c.1191G>C p.R397S | Missense Mutation (SNP) | VAF 81/322 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- PPP2R1B | c.1416A>C p.E472D | Missense Mutation (SNP) | VAF 60/210 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- PRAMEF14 | c.134G>T p.R45L | Missense Mutation (SNP) | VAF 73/540 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PRAMEF19 | c.121G>T p.V41L | Missense Mutation (SNP) | VAF 82/582 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, varscan2
- PROM2 | c.1813G>C p.D605H | Missense Mutation (SNP) | VAF 119/517 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- PSG3 | c.19C>T p.P7S | Missense Mutation (SNP) | VAF 155/625 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- PSG8 | c.11T>C p.L4P | Missense Mutation (SNP) | VAF 121/509 reads (24%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTCD1 | c.1678A>C p.N560H | Missense Mutation (SNP) | VAF 175/569 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- PTF1A | c.703G>T p.G235W | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- PTPN4 | c.995G>T p.R332L | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RAD50 | c.1100G>T p.R367I | Missense Mutation (SNP) | VAF 110/332 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- RAPSN | c.828G>A p.M276I | Missense Mutation (SNP) | VAF 215/965 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- RASAL3 | c.2017C>G p.P673A | Missense Mutation (SNP) | VAF 172/511 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- RECQL | c.1946C>A p.A649D | Missense Mutation (SNP) | VAF 65/309 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- RHOT2 | c.1372G>C p.V458L | Missense Mutation (SNP) | VAF 34/377 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.19); called by muse, mutect2
- RNF10 | c.727A>G p.I243V | Missense Mutation (SNP) | VAF 61/250 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RNF123 | c.2985G>T p.E995D | Missense Mutation (SNP) | VAF 113/398 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2
- SBF1 | c.4087-2A>T p.X1363_splice | Splice Site (SNP) | VAF 32/230 reads (14%) | called by muse, mutect2, varscan2
- SCGB1D1 | c.157C>G p.L53V | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.009); called by muse, mutect2
- SCN7A | c.3153G>T p.L1051F | Missense Mutation (SNP) | VAF 57/191 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- SCN8A | c.1207G>C p.V403L | Missense Mutation (SNP) | VAF 56/371 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- SDK2 | c.448G>T p.D150Y | Missense Mutation (SNP) | VAF 26/258 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- SEC16A | c.253G>T p.G85W | Missense Mutation (SNP) | VAF 103/288 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- SEC16B | c.1248G>T p.W416C | Missense Mutation (SNP) | VAF 30/271 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- SEMA3E | c.2246G>T p.W749L | Missense Mutation (SNP) | VAF 70/498 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SEMA6D | c.1330G>T p.E444* | Nonsense Mutation (SNP) | VAF 70/230 reads (30%) | called by muse, mutect2, varscan2
- SENP1 | c.583A>T p.R195* | Nonsense Mutation (SNP) | VAF 74/248 reads (30%) | called by muse, mutect2, varscan2
- SEZ6 | c.1767C>A p.C589* | Nonsense Mutation (SNP) | VAF 10/53 reads (19%) | called by muse, mutect2
- SHARPIN | c.985C>A p.P329T | Missense Mutation (SNP) | VAF 35/163 reads (21%) | SIFT tolerated (0.75); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SIRPA | c.552G>T p.W184C | Missense Mutation (SNP) | VAF 178/720 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SKOR2 | c.1420C>G p.R474G | Missense Mutation (SNP) | VAF 15/163 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.3); called by muse, mutect2
- SLC2A12 | c.580C>A p.H194N | Missense Mutation (SNP) | VAF 78/327 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC35A5 | c.429-1G>T p.X143_splice | Splice Site (SNP) | VAF 31/167 reads (19%) | called by muse, mutect2, varscan2
- SLC7A10 | c.1406G>C p.W469S | Missense Mutation (SNP) | VAF 91/931 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2
- SLC7A14 | c.434T>C p.I145T | Missense Mutation (SNP) | VAF 168/927 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLTM | c.152G>A p.R51Q | Missense Mutation (SNP) | VAF 26/169 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- SNED1 | c.1336G>T p.D446Y | Missense Mutation (SNP) | VAF 48/346 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- SOX3 | c.10G>T p.V4F | Missense Mutation (SNP) | VAF 284/554 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- SPATA32 | c.886C>G p.L296V | Missense Mutation (SNP) | VAF 69/265 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- SPECC1L | c.2155A>C p.K719Q | Missense Mutation (SNP) | VAF 112/381 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SRSF4 | c.607A>G p.K203E | Missense Mutation (SNP) | VAF 109/421 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SSTR4 | c.621G>T p.W207C | Missense Mutation (SNP) | VAF 137/321 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SYNE1 | c.2626A>T p.S876C (on ENST00000367255 / NM_182961.4; = p.S883C on NM_033071.3) | Missense Mutation (SNP) | VAF 52/224 reads (23%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- TACR3 | c.1196G>C p.S399T | Missense Mutation (SNP) | VAF 156/530 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- TAS2R39 | c.491T>A p.L164Q | Missense Mutation (SNP) | VAF 48/399 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TIGIT | c.590del p.P197Qfs*33 | Frame Shift Del (DEL) | VAF 152/933 reads (16%) | called by mutect2, pindel, varscan2
- TLCD3B | c.274A>T p.M92L | Missense Mutation (SNP) | VAF 100/608 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TMEM108 | c.508G>T p.G170C | Missense Mutation (SNP) | VAF 137/698 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- TMEM132C | c.540G>T p.E180D | Missense Mutation (SNP) | VAF 145/456 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- TNRC18 | c.5701G>T p.E1901* | Nonsense Mutation (SNP) | VAF 43/150 reads (29%) | called by muse, mutect2, varscan2
- TPR | c.3857T>C p.L1286P | Missense Mutation (SNP) | VAF 28/191 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- TRIM49C | c.18A>T p.L6F | Missense Mutation (SNP) | VAF 60/309 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- TRIM58 | c.440T>A p.L147Q | Missense Mutation (SNP) | VAF 63/224 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- TTN | c.92297T>C p.I30766T (on ENST00000591111; = p.I23342T on NM_003319.4) | Missense Mutation (SNP) | VAF 23/84 reads (27%) | PolyPhen benign (0.178); called by muse, mutect2, varscan2
- TTN | c.8227A>T p.N2743Y (on ENST00000591111; = p.N2697Y on NM_003319.4) | Missense Mutation (SNP) | VAF 102/444 reads (23%) | PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- TUBA1B | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 92/482 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- UNC45B | c.1015C>T p.P339S | Missense Mutation (SNP) | VAF 25/193 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- USH2A | c.4115C>T p.P1372L | Missense Mutation (SNP) | VAF 60/439 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- VWA3B | c.2621C>A p.S874Y | Missense Mutation (SNP) | VAF 87/402 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.547); called by muse, mutect2, varscan2
- WDR53 | c.16A>G p.T6A | Missense Mutation (SNP) | VAF 33/191 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.022); called by muse, varscan2
- WDR6 | c.262G>C p.G88R | Missense Mutation (SNP) | VAF 80/224 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WNT10A | c.883C>A p.H295N | Missense Mutation (SNP) | VAF 99/364 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZACN | c.1021G>C p.G341R | Missense Mutation (SNP) | VAF 127/521 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- ZNF215 | c.616G>T p.A206S | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT tolerated (0.82); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ZNF285 | c.1139del p.G380Afs*184 | Frame Shift Del (DEL) | VAF 64/288 reads (22%) | called by mutect2, pindel, varscan2
- ZNF480 | c.73-22_90del p.X25_splice | Splice Site (DEL) | VAF 43/247 reads (17%) | called by mutect2, pindel
- ZNF683 | c.431G>T p.G144V | Missense Mutation (SNP) | VAF 41/196 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- ZNF773 | c.476G>T p.S159I | Missense Mutation (SNP) | VAF 109/302 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.361); called by mutect2, varscan2
- ABCB7 | c.1512A>T p.V504= (on ENST00000373394 / NM_001271696.3; = p.V505= on NM_004299.6) | Silent (SNP) | VAF 102/225 reads (45%) | called by muse, mutect2, varscan2
- ABCC3 | c.3792C>T p.S1264= | Silent (SNP) | VAF 66/225 reads (29%) | catalogued as rs910150546; called by muse, mutect2, varscan2
- AC138647.1 | c.201C>T p.F67= | Silent (SNP) | VAF 88/868 reads (10%) | called by muse, mutect2
- ACTC1 | c.918T>A p.T306= | Silent (SNP) | VAF 39/141 reads (28%) | catalogued as rs397517074, COSV51760436; ClinVar: likely benign; called by muse, mutect2, varscan2
- AGMO | c.222G>A p.T74= | Silent (SNP) | VAF 14/158 reads (9%) | catalogued as rs533177176, COSV61118286, COSV61120470; called by muse, mutect2
- AL121899.2 | c.1776A>G p.T592= | Silent (SNP) | VAF 46/383 reads (12%) | called by muse, mutect2, varscan2
- APMAP | c.954G>T p.V318= | Silent (SNP) | VAF 224/484 reads (46%) | called by muse, mutect2, varscan2
- ARHGAP4 | c.2376G>A p.R792= | Silent (SNP) | VAF 100/154 reads (65%) | catalogued as COSV61687244; called by muse, mutect2, varscan2
- ATF7IP | c.3108C>A p.T1036= | Silent (SNP) | VAF 31/275 reads (11%) | called by muse, mutect2, varscan2
- ATP7B | c.960T>A p.P320= | Silent (SNP) | VAF 99/511 reads (19%) | called by muse, mutect2, varscan2
- BRD1 | c.2049G>T p.L683= | Silent (SNP) | VAF 74/259 reads (29%) | called by muse, mutect2, varscan2
- CACNA1E | c.2482C>A p.R828= | Silent (SNP) | VAF 17/112 reads (15%) | catalogued as COSV62381010; called by muse, mutect2
- CAMSAP2 | c.2580A>G p.L860= (on ENST00000236925 / NM_001297707.2; = p.L849= on NM_203459.3) | Silent (SNP) | VAF 61/244 reads (25%) | catalogued as rs1443134335, COSV52667023; called by muse, mutect2, varscan2
- CCS | c.651C>T p.I217= | Silent (SNP) | VAF 12/100 reads (12%) | called by muse, mutect2, varscan2
- CLN5 | c.21G>T p.T7= | Silent (SNP) | VAF 260/745 reads (35%) | catalogued as rs1057521258, COSV66283447; ClinVar: likely benign; called by muse, mutect2, varscan2
- CLSTN1 | c.1788G>A p.G596= (on ENST00000377298 / NM_001009566.3; = p.G586= on NM_014944.4) | Silent (SNP) | VAF 43/441 reads (10%) | called by muse, mutect2
- CUX2 | c.2262C>T p.P754= | Silent (SNP) | VAF 122/395 reads (31%) | catalogued as rs1191647616, COSV55633431; called by muse, mutect2, varscan2
- DCAF12L1 | c.558C>T p.C186= | Silent (SNP) | VAF 183/380 reads (48%) | called by muse, mutect2, varscan2
- DEFB107A | c.12C>A p.A4= | Silent (SNP) | VAF 10/79 reads (13%) | catalogued as rs1172311858; called by mutect2, varscan2
- DLGAP3 | c.2031G>T p.V677= | Silent (SNP) | VAF 18/186 reads (10%) | catalogued as rs767383249; called by muse, mutect2, varscan2
- DNAH7 | c.7326C>G p.R2442= | Silent (SNP) | VAF 107/474 reads (23%) | catalogued as COSV56782636; called by muse, mutect2, varscan2
- DST | c.18222C>T p.D6074= (on ENST00000361203 / NM_001374722.1; = p.D3771= on NM_015548.5) | Silent (SNP) | VAF 40/177 reads (23%) | called by muse, mutect2, varscan2
- DUSP15 | c.330C>T p.D110= (on ENST00000278979 / NM_001320479.1; = p.D113= on NM_080611.4) | Silent (SNP) | VAF 124/398 reads (31%) | catalogued as rs140560517; called by muse, mutect2, varscan2
- DYSF | c.2016C>A p.I672= | Silent (SNP) | VAF 261/990 reads (26%) | catalogued as COSV50336798; called by muse, varscan2
- EPS8L2 | c.531C>T p.G177= | Silent (SNP) | VAF 178/738 reads (24%) | called by muse, mutect2, varscan2
- ERLIN2 | c.642G>T p.A214= | Silent (SNP) | VAF 2983/3535 reads (84%) | catalogued as rs763446389, COSV99379629; called by muse, mutect2, varscan2
- EXOC3L2 | c.1287C>T p.A429= | Silent (SNP) | VAF 103/503 reads (20%) | called by muse, mutect2, varscan2
- FAM222A | c.582C>T p.S194= | Silent (SNP) | VAF 96/261 reads (37%) | called by muse, mutect2, varscan2
- FGF13 | c.585G>C p.L195= | Silent (SNP) | VAF 95/177 reads (54%) | called by muse, mutect2, varscan2
- FLG2 | c.5922C>T p.H1974= | Silent (SNP) | VAF 76/593 reads (13%) | called by muse, mutect2, varscan2
- FTHL17 | c.111T>C p.S37= | Silent (SNP) | VAF 101/245 reads (41%) | catalogued as COSV100784402; called by muse, mutect2, varscan2
- G6PC2 | c.612G>T p.L204= | Silent (SNP) | VAF 171/504 reads (34%) | called by muse, mutect2, varscan2
- GLI3 | c.795C>A p.A265= | Silent (SNP) | VAF 195/745 reads (26%) | called by muse, mutect2, varscan2
- GRID2IP | c.285C>T p.P95= | Silent (SNP) | VAF 18/124 reads (15%) | catalogued as rs1449124029; called by muse, mutect2, varscan2
- GUCY2C | c.2115C>A p.R705= | Silent (SNP) | VAF 74/371 reads (20%) | called by muse, mutect2, varscan2
- H3C13 | c.102C>A p.G34= | Silent (SNP) | VAF 101/774 reads (13%) | called by muse, mutect2, varscan2
- HELZ2 | c.1824G>T p.R608= (on ENST00000467148 / NM_001037335.2; = p.R39= on NM_033405.3) | Silent (SNP) | VAF 218/906 reads (24%) | called by muse, mutect2, varscan2
- HIVEP1 | c.2541T>C p.Y847= | Silent (SNP) | VAF 36/329 reads (11%) | catalogued as COSV101044852; called by muse, mutect2, varscan2
- KCND2 | c.1293C>T p.A431= | Silent (SNP) | VAF 56/502 reads (11%) | called by muse, mutect2, varscan2
- KDM4A | c.222G>T p.L74= | Silent (SNP) | VAF 28/271 reads (10%) | called by muse, mutect2, varscan2
- KIF26B | c.441C>T p.L147= | Silent (SNP) | VAF 125/571 reads (22%) | catalogued as rs1268035438; called by muse, mutect2, varscan2
- LAMA1 | c.2916C>A p.V972= | Silent (SNP) | VAF 67/501 reads (13%) | called by muse, mutect2, varscan2
- MRGPRX4 | c.159C>A p.G53= | Silent (SNP) | VAF 95/359 reads (26%) | called by muse, mutect2, varscan2
- MRGPRX4 | c.435G>T p.L145= | Silent (SNP) | VAF 93/443 reads (21%) | called by muse, mutect2, varscan2
- MUC5B | c.4773C>T p.Y1591= | Silent (SNP) | VAF 16/412 reads (4%) | called by muse, mutect2
- MYH1 | c.2052T>C p.T684= | Silent (SNP) | VAF 10/240 reads (4%) | called by muse, mutect2
- MYO15A | c.6474T>C p.F2158= | Silent (SNP) | VAF 34/556 reads (6%) | called by muse, mutect2
- MYO15B | c.3906G>T p.V1302= | Silent (SNP) | VAF 172/626 reads (27%) | called by muse, mutect2, varscan2
- NAGPA | c.1368G>T p.A456= | Silent (SNP) | VAF 148/532 reads (28%) | catalogued as COSV56569309; called by muse, mutect2, varscan2
- NELL2 | c.276C>G p.T92= | Silent (SNP) | VAF 39/193 reads (20%) | called by muse, mutect2, varscan2
- NFATC2IP | c.345G>C p.L115= | Silent (SNP) | VAF 10/21 reads (48%) | called by muse, mutect2, varscan2
- NFIA | c.1497C>T p.I499= | Silent (SNP) | VAF 95/382 reads (25%) | called by muse, mutect2, varscan2
- NIPA2 | c.102C>T p.G34= | Silent (SNP) | VAF 9/278 reads (3%) | catalogued as rs1355186213; called by muse, mutect2
- NPY1R | c.480T>C p.A160= | Silent (SNP) | VAF 90/240 reads (38%) | called by muse, mutect2
- NTM | c.471C>T p.C157= | Silent (SNP) | VAF 41/283 reads (14%) | catalogued as rs767253443; called by muse, mutect2, varscan2
- NUTM1 | c.612C>T p.S204= | Silent (SNP) | VAF 60/605 reads (10%) | called by muse, mutect2
- OR11H4 | c.849C>A p.I283= | Silent (SNP) | VAF 30/203 reads (15%) | catalogued as COSV59560946; called by muse, mutect2, varscan2
- OR2T34 | c.576C>T p.L192= | Silent (SNP) | VAF 41/411 reads (10%) | catalogued as rs1204486157; called by muse, mutect2, varscan2
- OR4N2 | c.144C>T p.T48= | Silent (SNP) | VAF 90/559 reads (16%) | called by muse, mutect2, varscan2
- OR5J2 | c.87G>T p.V29= | Silent (SNP) | VAF 40/190 reads (21%) | catalogued as COSV56623832; called by muse, mutect2, varscan2
- PCDH7 | c.1257G>A p.K419= | Silent (SNP) | VAF 42/302 reads (14%) | called by muse, mutect2, varscan2
- PGA3 | c.201C>T p.P67= | Silent (SNP) | VAF 54/435 reads (12%) | catalogued as COSV100337369, COSV57711923; called by muse, mutect2, varscan2
- PIP5KL1 | c.168G>T p.T56= | Silent (SNP) | VAF 108/297 reads (36%) | called by muse, mutect2, varscan2
- PKD1L3 | c.4947C>T p.V1649= | Silent (SNP) | VAF 34/91 reads (37%) | called by muse, mutect2, varscan2
- POM121L12 | c.408G>T p.P136= | Silent (SNP) | VAF 122/591 reads (21%) | catalogued as rs755206617, COSV68692208; called by muse, mutect2, varscan2
- PPP2R1A | c.201G>T p.L67= | Silent (SNP) | VAF 102/415 reads (25%) | called by muse, varscan2
- PPP4R3C | c.1728C>A p.I576= | Silent (SNP) | VAF 37/93 reads (40%) | called by muse, mutect2, varscan2
- PRAMEF17 | c.786A>G p.P262= | Silent (SNP) | VAF 223/795 reads (28%) | called by muse, mutect2, varscan2
- PRR35 | c.771C>T p.R257= | Silent (SNP) | VAF 67/195 reads (34%) | called by muse, mutect2, varscan2
- PRR35 | c.1221C>T p.D407= | Silent (SNP) | VAF 27/234 reads (12%) | called by muse, mutect2
- RABAC1 | c.480G>T p.L160= | Silent (SNP) | VAF 56/232 reads (24%) | called by muse, mutect2, varscan2
- RHBDL1 | c.193C>A p.R65= | Silent (SNP) | VAF 62/196 reads (32%) | catalogued as rs1021135609; called by muse, mutect2, varscan2
- RHOXF1 | c.234G>C p.R78= | Silent (SNP) | VAF 38/73 reads (52%) | called by muse, mutect2, varscan2
- RNF213 | c.3609G>C p.S1203= | Silent (SNP) | VAF 84/523 reads (16%) | catalogued as rs943130448, COSV71705519; called by muse, mutect2, varscan2
- SCUBE1 | c.1332G>T p.S444= | Silent (SNP) | VAF 90/279 reads (32%) | called by muse, mutect2, varscan2
- SDS | c.825C>A p.A275= | Silent (SNP) | VAF 125/444 reads (28%) | called by muse, mutect2, varscan2
- SEC16B | c.318A>G p.S106= | Silent (SNP) | VAF 27/181 reads (15%) | catalogued as rs1340868473; called by muse, mutect2, varscan2
- SH3YL1 | c.552C>T p.I184= | Silent (SNP) | VAF 84/307 reads (27%) | catalogued as rs1293139246; called by muse, mutect2, varscan2
- SIPA1L1 | c.2610G>A p.K870= | Silent (SNP) | VAF 27/196 reads (14%) | called by muse, mutect2, varscan2
- SLC23A2 | c.1140C>A p.V380= | Silent (SNP) | VAF 43/140 reads (31%) | catalogued as COSV57771239; called by muse, mutect2, varscan2
- SLC35G5 | c.978G>T p.R326= | Silent (SNP) | VAF 58/472 reads (12%) | called by muse, mutect2, varscan2
- SMC1B | c.3438C>G p.A1146= | Silent (SNP) | VAF 20/161 reads (12%) | called by muse, mutect2, varscan2
- SNX19 | c.2367A>G p.Q789= | Silent (SNP) | VAF 133/482 reads (28%) | catalogued as rs1251096271; called by muse, mutect2, varscan2
- SRRM3 | c.1341T>C p.S447= | Silent (SNP) | VAF 49/206 reads (24%) | called by muse, mutect2, varscan2
- SRSF8 | c.630G>A p.S210= | Silent (SNP) | VAF 94/411 reads (23%) | called by muse, mutect2, varscan2
- STAT5A | c.63G>T p.L21= | Silent (SNP) | VAF 84/366 reads (23%) | called by muse, mutect2, varscan2
- STRIP1 | c.2139G>T p.V713= | Silent (SNP) | VAF 118/562 reads (21%) | called by mutect2, varscan2
- TAC1 | c.250T>C p.L84= | Silent (SNP) | VAF 39/166 reads (23%) | called by muse, mutect2, varscan2
- TBC1D16 | c.147G>C p.P49= | Silent (SNP) | VAF 120/444 reads (27%) | called by muse, mutect2, varscan2
- TBX5 | c.33G>C p.A11= | Silent (SNP) | VAF 133/1043 reads (13%) | catalogued as COSV59866633; called by muse, mutect2, varscan2
- TLCD3B | c.273C>G p.A91= | Silent (SNP) | VAF 99/599 reads (17%) | called by muse, mutect2, varscan2
- TMPRSS15 | c.1617T>C p.S539= | Silent (SNP) | VAF 208/499 reads (42%) | called by muse, mutect2, varscan2
- TRHDE | c.1296G>T p.L432= | Silent (SNP) | VAF 34/268 reads (13%) | called by muse, mutect2, varscan2
- TRIM31 | c.216G>A p.R72= | Silent (SNP) | VAF 23/196 reads (12%) | catalogued as rs770193310; called by muse, mutect2, varscan2
- TRIM42 | c.1827C>A p.I609= | Silent (SNP) | VAF 52/213 reads (24%) | catalogued as rs779318987; called by muse, mutect2, varscan2
- TRPC4AP | c.1176C>G p.L392= | Silent (SNP) | VAF 39/220 reads (18%) | catalogued as rs554067666; called by muse, mutect2, varscan2
- WASF3 | c.117C>G p.R39= | Silent (SNP) | VAF 40/165 reads (24%) | called by muse, mutect2, varscan2
- WDR33 | c.2172C>T p.G724= | Silent (SNP) | VAF 90/338 reads (27%) | called by muse, mutect2, varscan2
- WT1 | c.1494C>A p.L498= | Silent (SNP) | VAF 145/667 reads (22%) | called by muse, mutect2, varscan2
- WWC1 | c.1563G>T p.L521= | Silent (SNP) | VAF 85/311 reads (27%) | called by muse, mutect2, varscan2
- XKR7 | c.1510C>A p.R504= | Silent (SNP) | VAF 45/225 reads (20%) | catalogued as rs530229497, COSV73813066; called by muse, mutect2, varscan2
- ZAN | c.6550C>T p.L2184= | Silent (SNP) | VAF 138/488 reads (28%) | catalogued as rs1010920246; called by muse, mutect2, varscan2
- ZNF334 | c.435T>C p.T145= | Silent (SNP) | VAF 67/188 reads (36%) | called by muse, mutect2, varscan2
- ZNF439 | c.1494C>T p.T498= | Silent (SNP) | VAF 21/74 reads (28%) | called by muse, mutect2, varscan2
- ZNF683 | c.432G>T p.G144= | Silent (SNP) | VAF 40/195 reads (21%) | called by muse, mutect2, varscan2
- ABI3BP | c.1576+11679A>C | Intron (SNP) | VAF 60/480 reads (13%) | called by muse, mutect2, varscan2
- AC079612.1 | n.299C>A | RNA (SNP) | VAF 224/860 reads (26%) | called by muse, mutect2, varscan2
- AC244517.10 | c.36-8878A>G | Intron (SNP) | VAF 261/745 reads (35%) | catalogued as COSV101595512; called by muse, mutect2, varscan2
- ADAP1 | c.214-501A>C | Intron (SNP) | VAF 52/218 reads (24%) | called by muse, mutect2, varscan2
- AGAP3 | c.46-27G>A | Intron (SNP) | VAF 9/50 reads (18%) | called by muse, mutect2, varscan2
- AHRR | c.442-1487del | Intron (DEL) | VAF 162/846 reads (19%) | catalogued as COSV57086549; called by mutect2, pindel, varscan2
- AL353753.1 | n.520del | RNA (DEL) | VAF 33/188 reads (18%) | called by mutect2, pindel, varscan2
- AL353804.4 | chrX:73825174 G>T | 5'Flank (SNP) | VAF 87/206 reads (42%) | called by muse, mutect2, varscan2
- ALG2 | c.*1424G>C | 3'UTR (SNP) | VAF 10/74 reads (14%) | called by muse, mutect2
- ARHGEF25 | chr12:57620285 G>T | 3'Flank (SNP) | VAF 58/264 reads (22%) | called by muse, mutect2, varscan2
- ASL | c.656-42C>G | Intron (SNP) | VAF 77/473 reads (16%) | catalogued as rs751604140; called by muse, mutect2, varscan2
- C7orf66 | n.114C>T | RNA (SNP) | VAF 58/258 reads (22%) | called by muse, mutect2, varscan2
- CDH15 | chr16:89168990 T>C | 5'Flank (SNP) | VAF 10/26 reads (38%) | catalogued as rs978650138; called by muse, varscan2
- CLUHP11 | n.222C>A | RNA (SNP) | VAF 9/79 reads (11%) | called by muse, mutect2, varscan2
- CLUHP11 | n.223C>A | RNA (SNP) | VAF 9/80 reads (11%) | called by muse, mutect2, varscan2
- CPAMD8 | c.5567+89_5567+118del | Intron (DEL) | VAF 96/276 reads (35%) | called by mutect2, pindel
- CYB5R3 | c.-61G>C | 5'UTR (SNP) | VAF 6/40 reads (15%) | called by muse, mutect2
- DCD | c.290-169T>C | Intron (SNP) | VAF 115/394 reads (29%) | catalogued as rs943743153; called by muse, mutect2, varscan2
- DST | c.4296+3884G>T | Intron (SNP) | VAF 51/192 reads (27%) | called by muse, mutect2, varscan2
- DUSP3 | c.*58C>G | 3'UTR (SNP) | VAF 19/154 reads (12%) | called by muse, mutect2, varscan2
- EFL1P1 | n.1767G>T | RNA (SNP) | VAF 35/155 reads (23%) | called by muse, mutect2, varscan2
- EPCAM | chr2:47369147 C>T | 5'Flank (SNP) | VAF 27/174 reads (16%) | called by muse, mutect2, varscan2
- ERLIN2 | chr8:37736381 C>G | 5'Flank (SNP) | VAF 78/3168 reads (2%) | called by muse, mutect2
- FAM227B | c.1013-24847C>G | Intron (SNP) | VAF 21/46 reads (46%) | called by muse, mutect2, varscan2
- FGFR3 | c.*1058G>A | 3'UTR (SNP) | VAF 37/818 reads (5%) | called by muse, mutect2
- G6PC3 | c.-35G>T | 5'UTR (SNP) | VAF 101/676 reads (15%) | called by muse, mutect2, varscan2
- GDAP1 | c.*1281A>G | 3'UTR (SNP) | VAF 17/630 reads (3%) | catalogued as rs1296734238; called by muse, mutect2
- GON4L | c.5631+46G>T | Intron (SNP) | VAF 57/488 reads (12%) | catalogued as rs184600939; called by muse, mutect2, varscan2
- GRM6 | c.2125-239C>A | Intron (SNP) | VAF 136/358 reads (38%) | called by muse, mutect2, varscan2
- HEBP2 | chr6:138403653 G>T | 5'Flank (SNP) | VAF 8/35 reads (23%) | called by muse, mutect2, varscan2
- HGFAC | c.1103-148G>T | Intron (SNP) | VAF 57/368 reads (15%) | called by muse, mutect2, varscan2
- ICAM5 | c.-38G>C | 5'UTR (SNP) | VAF 37/264 reads (14%) | catalogued as rs756790595; called by muse, mutect2, varscan2
- IGFN1 | c.1241+683G>C | Intron (SNP) | VAF 54/248 reads (22%) | catalogued as rs774994028; called by muse, mutect2, varscan2
- KIAA0895 | c.867+10C>A | Intron (SNP) | VAF 69/214 reads (32%) | called by muse, mutect2, varscan2
- LAMB3 | c.*3C>T | 3'UTR (SNP) | VAF 37/363 reads (10%) | called by muse, mutect2, varscan2
- LMO2 | c.-120G>A | 5'UTR (SNP) | VAF 43/168 reads (26%) | catalogued as rs757485203; called by muse, mutect2, varscan2
- LSM14B | c.*171G>C | 3'UTR (SNP) | VAF 78/316 reads (25%) | called by muse, mutect2, varscan2
- LYSMD3 | c.-94C>A | 5'UTR (SNP) | VAF 86/450 reads (19%) | called by muse, mutect2, varscan2
- MGAT4FP | n.724A>T | RNA (SNP) | VAF 26/194 reads (13%) | called by muse, mutect2, varscan2
- MPRIP | c.2163+4045G>C | Intron (SNP) | VAF 94/314 reads (30%) | called by muse, mutect2, varscan2
- MPRIP | c.2163+4046G>T | Intron (SNP) | VAF 96/318 reads (30%) | called by muse, mutect2, varscan2
- NIP7 | c.56+15G>C | Intron (SNP) | VAF 108/293 reads (37%) | called by muse, mutect2, varscan2
- NIPSNAP1 | c.-8G>T | 5'UTR (SNP) | VAF 74/561 reads (13%) | called by muse, mutect2, varscan2
- OPCML | c.937+922T>C | Intron (SNP) | VAF 24/490 reads (5%) | called by muse, mutect2
- PCDH15 | c.92-523T>A | Intron (SNP) | VAF 35/147 reads (24%) | called by muse, mutect2, varscan2
- POTEM | c.811-1222C>A | Intron (SNP) | VAF 159/1898 reads (8%) | catalogued as rs1357069808; called by muse, mutect2
- PRSS40A | n.142-2276G>C | Intron (SNP) | VAF 110/984 reads (11%) | called by muse, mutect2, varscan2
- RAB13 | c.246+10G>T | Intron (SNP) | VAF 28/226 reads (12%) | catalogued as rs762679129; called by muse, mutect2, varscan2
- RNF224 | c.-22G>A | 5'UTR (SNP) | VAF 70/174 reads (40%) | catalogued as rs1171831298; called by muse, mutect2, varscan2
- RYR3 | c.10023+20C>A | Intron (SNP) | VAF 30/293 reads (10%) | catalogued as COSV66791680; called by muse, mutect2, varscan2
- SATL1 | c.-125C>A | 5'UTR (SNP) | VAF 296/471 reads (63%) | called by muse, mutect2, varscan2
- SDHA | c.1064+20A>G | Intron (SNP) | VAF 57/608 reads (9%) | called by muse, mutect2
- SEC61A2 | c.-103G>T | 5'UTR (SNP) | VAF 97/312 reads (31%) | called by muse, mutect2, varscan2
- SEM1 | c.*40G>T | 3'UTR (SNP) | VAF 52/183 reads (28%) | called by muse, mutect2, varscan2
- SGIP1 | c.472-1182A>T | Intron (SNP) | VAF 14/67 reads (21%) | called by muse, mutect2, varscan2
- SMPD4 | c.1215-95C>T | Intron (SNP) | VAF 141/560 reads (25%) | catalogued as rs1473210904; called by muse, mutect2, varscan2
- SNORD116-5 | n.14G>A | RNA (SNP) | VAF 45/428 reads (11%) | called by muse, mutect2, varscan2
- STX4 | chr16:31033501 G>T | 5'Flank (SNP) | VAF 47/262 reads (18%) | catalogued as rs1461945942; called by muse, mutect2, varscan2
- TSHR | c.692+236C>A | Intron (SNP) | VAF 72/511 reads (14%) | called by muse, mutect2, varscan2
- TTC16 | c.1764+51C>T | Intron (SNP) | VAF 10/63 reads (16%) | catalogued as rs56231836; called by muse, mutect2, varscan2
- TUBBP5 | n.1210G>C | RNA (SNP) | VAF 253/764 reads (33%) | catalogued as rs1308039654; called by muse, varscan2
- TXNRD3 | n.737G>T | RNA (SNP) | VAF 56/262 reads (21%) | called by muse, mutect2, varscan2
- UNC5D | c.1303+1842A>G | Intron (SNP) | VAF 13/40 reads (33%) | called by muse, mutect2, varscan2
- VWA5B2 | c.530+56G>A | Intron (SNP) | VAF 11/137 reads (8%) | catalogued as rs1346783527; called by muse, mutect2
- WT1 | chr11:32439838 T>C | 5'Flank (SNP) | VAF 71/350 reads (20%) | called by muse, mutect2, varscan2
- Y_RNA | chr7:23490751 C>A | 3'Flank (SNP) | VAF 125/395 reads (32%) | called by muse, mutect2, varscan2
